Somatic mutation profile of tumor specimen TCGA-AA-3947-01A (aliquot TCGA-AA-3947-01A-01D-1981-10) from TCGA case TCGA-AA-3947, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.3 years (22,035 days).
Specimen TCGA-AA-3947-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2dcfbe6c-60bd-4302-818d-00a7d9500a71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3947-10A (Blood Derived Normal), aliquot TCGA-AA-3947-10A-01D-1982-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86117d2a-b07d-4d12-aebd-736c877b165f

The open-access MAF lists 2,649 somatic variants for this specimen: 2,034 protein-altering or splice-affecting, 566 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,479, Silent 566, Frame Shift Del 337, Frame Shift Ins 93, Nonsense Mutation 58, Splice Site 31, Intron 23, Splice Region 17, In Frame Del 16, 3'UTR 13, RNA 10, 5'Flank 2.

Variants (750 of 2,649; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 54/154 reads (35%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL4A5 | c.2741G>A p.G914D | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869025332, COSV100086574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRYAB | c.60del p.S21Afs*24 | Frame Shift Del (DEL) | VAF 104/279 reads (37%) | catalogued as rs281865141, CD112644; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DLL3 | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 69/169 reads (41%) | catalogued as rs104894675, CM031159; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs764670582, CM137950, COSV99246793, COSV99247244; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HAX1 | c.430dup p.V144Gfs*5 | Frame Shift Ins (INS) | VAF 47/112 reads (42%) | catalogued as rs770288337; ClinVar: pathogenic; called by mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ITGB2 | c.897+1G>A p.X299_splice | Splice Site (SNP) | VAF 68/211 reads (32%) | catalogued as rs201752283, CS1513870, CS151558, CS920765, COSV56610868; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MFRP | chr11:119346046 G>A | 5'Flank (SNP) | VAF 12/27 reads (44%) | catalogued as rs1359404443, CM135414, COSV100793350; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs727503258, COSV100805719; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 56/132 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.8677dup p.H2893Pfs*2 | Frame Shift Ins (INS) | VAF 99/303 reads (33%) | catalogued as rs1554221465; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- STK11 | c.842del p.P281Rfs*6 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TMEM216 | c.228dup p.G77Wfs*16 (on ENST00000515837 / NM_001173990.3; = p.G16Wfs*16 on NM_016499.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 157/1011 reads (16%) | catalogued as rs767384710; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- TNFRSF11B | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 161/451 reads (36%) | catalogued as rs1307942060, COSV52070601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as CD033696, COSV99966592; called by muse, mutect2, varscan2
- AADACL2 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100735686; called by muse, mutect2, varscan2
- AASS | c.2076del p.P693Qfs*3 | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | catalogued as rs768943469; called by mutect2, pindel, varscan2
- ABCA3 | c.1850T>G p.L617R | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068043; called by muse, mutect2, varscan2
- ABCA5 | c.426dup p.P143Sfs*2 | Frame Shift Ins (INS) | VAF 104/278 reads (37%) | catalogued as rs1354980064; called by mutect2, varscan2
- ABCA6 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 166/782 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as rs1237970782, COSV99445855; called by muse, mutect2
- ABCB10 | c.2011C>A p.L671I | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100747833; called by muse, mutect2
- ABCB8 | c.1387G>A p.V463I (on ENST00000297504 / NM_001282291.2; = p.V446I on NM_007188.5) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370506479; called by muse, mutect2, varscan2
- ABCB9 | c.2168C>T p.T723I (on ENST00000280560 / NM_019625.4; = p.T680I on NM_019624.3) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV54890769, COSV99757553; called by muse, mutect2, varscan2
- ABCC1 | c.4522T>C p.Y1508H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100578611; called by muse, mutect2, varscan2
- ABCC6 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs371804833, COSV99228094; called by muse, mutect2, varscan2
- ABCF3 | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV99491250, COSV99491370; called by muse, mutect2, varscan2
- ABL2 | c.3364G>T p.G1122C (on ENST00000502732 / NM_007314.4; = p.G1107C on NM_005158.5) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100772477; called by muse, mutect2, varscan2
- AC004922.1 | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV99500944; called by muse, varscan2
- AC006059.2 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV100045185; called by muse, mutect2, varscan2
- AC098582.1 | c.1684C>A p.L562I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV99985309; called by muse, mutect2, varscan2
- AC244197.3 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100557835; called by muse, mutect2, varscan2
- ACADSB | c.591T>G p.D197E | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100715086; called by muse, mutect2, varscan2
- ACE2 | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV53028006, COSV99382556; called by muse, mutect2, varscan2
- ACKR1 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63673936; called by muse, mutect2, varscan2
- ACSL5 | c.1592C>T p.P531L (on ENST00000354273; = p.P587L on NM_016234.3) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs375823791; called by muse, mutect2, varscan2
- ACSM1 | c.1366A>T p.M456L | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99532536; called by muse, mutect2
- ACTL6A | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); catalogued as COSV101199624; called by muse, mutect2, varscan2
- ACTR2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV53199572, COSV53201772; called by muse, mutect2, varscan2
- ADA | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100596077; called by muse, mutect2, varscan2
- ADAM15 | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99664727; called by muse, mutect2, varscan2
- ADAM22 | c.1077+1G>A p.X359_splice | Splice Site (SNP) | VAF 48/808 reads (6%) | catalogued as COSV99715813; called by muse, mutect2
- ADAM23 | c.1443A>T p.R481S | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV100006738; called by muse, mutect2, varscan2
- ADAMDEC1 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV56477841; called by muse, mutect2, varscan2
- ADAMTS10 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99546484; called by muse, mutect2, varscan2
- ADAMTS13 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs782733057, COSV100746955; called by muse, mutect2
- ADAMTS17 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs753474247, COSV51476592; called by mutect2, varscan2
- ADAMTS20 | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67132446; called by mutect2, varscan2
- ADAMTS3 | c.2706A>C p.Q902H | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.225); catalogued as COSV99710270; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1105A>G p.M369V | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV52809773; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); catalogued as rs146769560; called by muse, mutect2, varscan2
- ADCY4 | c.2014C>A p.L672I | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs763384611, COSV100156194, COSV60253135; called by muse, varscan2
- ADCY4 | c.752A>G p.Q251R | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99352947; called by muse, varscan2
- ADCY4 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.109); catalogued as COSV99352949; called by muse, mutect2, varscan2
- ADCY6 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.327); catalogued as COSV100326409; called by muse, mutect2, varscan2
- ADCY7 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1443297102, COSV99575693; called by muse, mutect2, varscan2
- ADD3 | c.1975G>A p.E659K (on ENST00000356080 / NM_001320591.2; = p.E627K on NM_001121.4) | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs753083630, COSV99523194; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376943659; called by muse, mutect2, varscan2
- ADGRG3 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs141398818; called by muse, mutect2, varscan2
- ADGRG6 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99745870; called by muse, varscan2
- ADGRL3 | c.1198A>G p.N400D (on ENST00000506720 / NM_001322402.2; = p.N332D on NM_015236.6) | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV101546867; called by muse, mutect2, varscan2
- ADGRV1 | c.2990T>C p.I997T | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101315520; called by muse, mutect2
- ADSL | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV53407861, COSV99342574; called by muse, mutect2, varscan2
- AEBP1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV56260995; called by muse, mutect2, varscan2
- AFM | c.1647-2A>G p.X549_splice | Splice Site (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99888494; called by muse, mutect2, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 74/183 reads (40%) | catalogued as COSV58317085; called by mutect2, varscan2
- AGAP3 | c.67del p.Q23Sfs*31 (on ENST00000622464; = p.Q59Sfs*31 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1554459038; called by mutect2, pindel
- AGBL1 | c.2611G>A p.A871T | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV101222268; called by muse, mutect2, varscan2
- AGBL5 | c.1223A>C p.Q408P | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100548880; called by muse, mutect2, varscan2
- AGO3 | c.764A>G p.H255R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV99868009; called by muse, mutect2, varscan2
- AGO4 | c.128A>T p.D43V | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100942770; called by muse, mutect2, varscan2
- AGPAT1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100421541; called by muse, mutect2, varscan2
- AHCTF1 | c.4819G>A p.D1607N (on ENST00000366508; = p.D1581N on NM_015446.5) | Missense Mutation (SNP) | VAF 200/421 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100403131; called by muse, mutect2, varscan2
- AHCY | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.056); catalogued as COSV99464017; called by muse, mutect2, varscan2
- AHNAK | c.15820G>A p.E5274K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.752); catalogued as rs144898392; called by muse, mutect2, varscan2
- AHNAK | c.2792G>A p.G931D | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57212591; called by muse, mutect2, varscan2
- AKAP11 | c.4894A>T p.I1632F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV99213536; called by muse, mutect2
- AKAP12 | c.3667G>T p.A1223S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99482458; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKAP9 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100661933; called by muse, mutect2
- AKAP9 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV62343434; called by muse, mutect2, varscan2
- AKNA | c.4061C>T p.A1354V | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV99799686; called by muse, mutect2, varscan2
- AKNAD1 | c.2039G>A p.C680Y | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.176); catalogued as COSV62196467, COSV62198398; called by muse, mutect2, varscan2
- ALDH18A1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1305993720, COSV64662642; called by muse, mutect2, varscan2
- ALK | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs1306212162, COSV66557635; called by muse, mutect2, varscan2
- ALOX12B | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs562084711, COSV59871674; called by muse, varscan2
- ALOX12B | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100046672; called by muse, varscan2
- ALPK1 | c.2701C>A p.L901I | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99453110; called by muse, mutect2, varscan2
- ALS2 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99968790; called by muse, mutect2, varscan2
- AMACR | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs201818706; called by muse, mutect2, varscan2
- AMDHD2 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as COSV53550555; called by muse, mutect2, varscan2
- AMER1 | c.3362C>T p.A1121V | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100365359; called by muse, mutect2
- AMIGO2 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99873442; called by muse, mutect2, varscan2
- AMTN | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV100219662; called by muse, mutect2, varscan2
- AMZ1 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100406188; called by muse, mutect2, varscan2
- ANAPC5 | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV99945950; called by muse, mutect2
- ANGPTL5 | c.1008C>G p.N336K | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs139900371, COSV100527643; called by muse, mutect2, varscan2
- ANK3 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99778447; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.56T>G p.V19G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV99782136; called by muse, mutect2, varscan2
- ANKK1 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.378); catalogued as COSV100392701; called by muse, varscan2
- ANKRD44 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774090343, COSV56550946; called by muse, mutect2, varscan2
- ANXA11 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV99626837; called by muse, mutect2, varscan2
- ANXA6 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs748009214, COSV62905611; called by muse, mutect2, varscan2
- ANXA9 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100929062; called by muse, mutect2, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- AOPEP | c.2063A>C p.N688T (on ENST00000375315 / NM_001193329.1; = p.N589T on NM_032823.5) | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99948786; called by muse, mutect2
- AOX1 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs373608049, COSV101021751; called by muse, mutect2, varscan2
- AP1S1 | c.158G>T p.R53M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV61760874; called by muse, mutect2, varscan2
- AP5Z1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as COSV100804002; called by muse, mutect2, varscan2
- APBB1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as rs367708086; called by mutect2, varscan2
- APC | c.1856C>A p.T619N | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1197473008, COSV99965481; ClinVar: uncertain significance; called by muse, mutect2
- APC | c.4537G>T p.E1513* | Nonsense Mutation (SNP) | VAF 60/162 reads (37%) | catalogued as COSV57348031; called by muse, mutect2, varscan2
- APMAP | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.524); catalogued as COSV99468203; called by muse, mutect2, varscan2
- APOA5 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99911176; called by muse, mutect2
- APOL5 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99968335; called by muse, mutect2
- AQP2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1486287656, COSV99550740; called by muse, mutect2, varscan2
- AQP7 | c.528G>C p.A176= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99952055; called by muse, varscan2
- AR | c.170_193del p.L57_Q64del | In Frame Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs749944495; called by mutect2, pindel, varscan2*
- ARC | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 29/124 reads (23%) | catalogued as COSV100751664; called by muse, mutect2, varscan2
- ARC | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100751665; called by muse, mutect2, varscan2
- ARFGAP2 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs372871965, COSV54067476; called by muse, mutect2, varscan2
- ARHGAP11A | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 98/328 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100853158; called by mutect2, varscan2
- ARHGAP21 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100903504; called by muse, mutect2, varscan2
- ARHGAP22 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1231366282, COSV99984513; called by muse, mutect2, varscan2
- ARHGAP25 | c.1276C>T p.P426S (on ENST00000409202 / NM_001007231.3; = p.P418S on NM_014882.3) | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99771077; called by muse, mutect2, varscan2
- ARHGAP28 | c.1307T>G p.L436R (on ENST00000383472 / NM_001366230.1; = p.L277R on NM_001010000.3) | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51632708, COSV51641871; called by muse, mutect2
- ARHGAP29 | c.1835C>T p.T612I | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99557673; called by muse, mutect2, varscan2
- ARHGAP30 | c.668G>A p.G223D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100920138; called by muse, mutect2, varscan2
- ARHGAP35 | c.2914dup p.R972Pfs*40 | Frame Shift Ins (INS) | VAF 30/118 reads (25%) | catalogued as rs1365296949; called by pindel, varscan2
- ARHGAP44 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.098); catalogued as COSV99310111; called by muse, mutect2, varscan2
- ARHGEF18 | c.1140G>T p.E380D (on ENST00000359920 / NM_001130955.2; = p.E276D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs1445369735, COSV100149024; called by muse, mutect2, varscan2
- ARID1A | c.1728G>T p.Q576H | Missense Mutation (SNP) | VAF 126/321 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV100250396; called by muse, mutect2, varscan2
- ARMC8 | c.388C>T p.R130C (on ENST00000469044 / NM_001363941.2; = p.R116C on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs1296721856, COSV61769325; called by muse, mutect2, varscan2
- ARSD | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as rs759116005, COSV99471985; called by muse, mutect2, varscan2
- ASAH2 | c.148dup p.S50Ffs*61 | Frame Shift Ins (INS) | VAF 60/252 reads (24%) | catalogued as rs772181094; called by mutect2, varscan2
- ASB18 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100430481; called by muse, mutect2, varscan2
- ASB9 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs1395816414, COSV100995377; called by muse, mutect2
- ASCC3 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 45/253 reads (18%) | catalogued as COSV100225259; called by muse, mutect2, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 38/174 reads (22%) | catalogued as rs747570359; called by mutect2, varscan2
- ASCL1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57152675; called by muse, mutect2, varscan2
- ATG9B | c.27del p.R10Efs*96 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs760721903; called by mutect2, varscan2
- ATP10A | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs1472174425, COSV100790893; called by muse, mutect2, varscan2
- ATP11C | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 196/543 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV100557432; called by muse, mutect2, varscan2
- ATP12A | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs756031037, COSV54518726; called by muse, mutect2, varscan2
- ATP2A1 | c.545-1G>T p.X182_splice | Splice Site (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100837085; called by muse, mutect2, varscan2
- ATP2A3 | c.1712dup p.R572Kfs*35 | Frame Shift Ins (INS) | VAF 14/69 reads (20%) | catalogued as rs779330933; called by mutect2, pindel, varscan2
- ATP2B3 | c.3347G>A p.R1116Q (on ENST00000263519 / NM_001001344.2; = p.P1167= on NM_021949.3) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs147050282, COSV99683109; called by muse, varscan2
- ATP6AP1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs868950779, COSV63895649; called by muse, mutect2, varscan2
- ATP6V0A2 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745357777, COSV100376825; called by muse, mutect2, varscan2
- ATP7B | c.3356C>A p.P1119H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.325); catalogued as COSV54439325; called by muse, mutect2, varscan2
- ATRN | c.3272C>G p.T1091S | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV53524673, COSV99496592; called by muse, mutect2, varscan2
- ATRX | c.2961G>T p.K987N | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV100970104; called by muse, mutect2, varscan2
- ATXN1 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99785086; called by muse, mutect2, varscan2
- ATXN3L | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101019318; called by muse, mutect2
- ATXN7 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs201198489; called by muse, mutect2, varscan2
- AUTS2 | c.1096T>C p.S366P | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.563); catalogued as COSV100715056; called by muse, mutect2, varscan2
- AUTS2 | c.2750C>A p.P917H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100715058; called by muse, mutect2, varscan2
- AWAT1 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100997173; called by muse, mutect2, varscan2
- AZIN2 | c.1192T>C p.F398L | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1283039093, COSV99612917; called by muse, mutect2, varscan2
- B3GNT4 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs150666707; called by muse, mutect2, varscan2
- B3GNT8 | c.390G>T p.W130C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99524438; called by muse, mutect2, varscan2
- BACH1 | c.432del p.K144Nfs*22 | Frame Shift Del (DEL) | VAF 66/206 reads (32%) | catalogued as rs748639705; called by mutect2, varscan2
- BAMBI | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as rs772888888, COSV65003190, COSV65003195; called by muse, mutect2, varscan2
- BANF2 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99856364; called by muse, mutect2, varscan2
- BAZ1B | c.2929G>A p.V977I | Missense Mutation (SNP) | VAF 257/638 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100289601; called by muse, mutect2, varscan2
- BCAM | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140735488, CM087623; called by muse, mutect2, varscan2
- BCL2L12 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99880881; called by muse, mutect2, varscan2
- BCL6B | c.546del p.S183Vfs*20 | Frame Shift Del (DEL) | VAF 67/224 reads (30%) | catalogued as COSV53426596; called by mutect2, pindel, varscan2
- BCL9 | c.3822G>T p.Q1274H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99324522; called by muse, mutect2, varscan2
- BCLAF1 | c.352_354del p.R118del | In Frame Del (DEL) | VAF 24/112 reads (21%) | catalogued as rs758471531; called by pindel, varscan2
- BDP1 | c.5557A>G p.T1853A | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100702746; called by muse, mutect2
- BEND2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1238581335, COSV101191809; called by muse, mutect2, varscan2
- BEND5 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 105/294 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as rs148822442; called by muse, varscan2
- BEX1 | c.338del p.P113Lfs*16 | Frame Shift Del (DEL) | VAF 119/301 reads (40%) | catalogued as COSV65579748; called by mutect2, pindel, varscan2
- BGLAP | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV52744778, COSV99430762; called by muse, mutect2, varscan2
- BHMT2 | c.336del p.I113Sfs*24 | Frame Shift Del (DEL) | VAF 97/269 reads (36%) | catalogued as rs36116756; called by mutect2, pindel, varscan2
- BICDL1 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs377763632; called by muse, mutect2, varscan2
- BIN1 | c.1618C>A p.Q540K (on ENST00000316724 / NM_001320642.1; = p.Q401K on NM_004305.4) | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV52115857, COSV99387530; called by muse, mutect2, varscan2
- BIRC2 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 115/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99926532; called by muse, mutect2, varscan2
- BIRC6 | c.11888C>A p.P3963Q | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101427858; called by muse, mutect2, varscan2
- BIRC6 | c.13226T>C p.V4409A | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV101427859; called by muse, mutect2, varscan2
- BLK | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 89/219 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs371256341; ClinVar: benign; called by muse, mutect2, varscan2
- BLK | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99376866; called by mutect2, varscan2
- BMP3 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs751449569, COSV99261400; called by muse, mutect2, varscan2
- BMP5 | c.863T>G p.L288R | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100895773, COSV63706311; called by muse, mutect2
- BMPR2 | c.76+1G>A p.X26_splice | Splice Site (SNP) | VAF 54/157 reads (34%) | catalogued as CS1513970, COSV65810969; called by muse, mutect2, varscan2
- BOLA1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113958238, COSV100975369; called by mutect2, varscan2
- BPIFB6 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs776796699, COSV62755553; called by muse, mutect2, varscan2
- BPTF | c.671T>A p.I224N | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100074136, COSV58831037; called by muse, mutect2
- BPTF | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs764527892, COSV58833907; called by muse, mutect2, varscan2
- BRCA2 | c.9888G>T p.K3296N | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101200842; called by muse, mutect2
- BRD3 | c.1522_1524del p.K508del | In Frame Del (DEL) | VAF 12/91 reads (13%) | catalogued as rs748848370; called by pindel, varscan2
- BRIP1 | c.2627G>A p.S876N | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.959); catalogued as rs750961319, COSV99369334; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRMS1L | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99396511; called by muse, mutect2, varscan2
- BRPF1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs755029735, COSV57403970; called by muse, mutect2, varscan2
- BRPF3 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1363623097, COSV100325570; called by muse, mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 16/38 reads (42%) | catalogued as rs746043904; called by mutect2, varscan2
- BSN | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99607344; called by muse, mutect2, varscan2
- BSN | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs752273895, COSV56522483; called by muse, mutect2, varscan2
- BTRC | c.962G>A p.R321Q (on ENST00000370187 / NM_033637.4; = p.R285Q on NM_003939.5) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1473075801, COSV64580831, COSV64581102; called by muse, mutect2, varscan2
- C10orf90 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99503151; called by muse, mutect2, varscan2
- C19orf73 | c.143del p.P48Hfs*9 | Frame Shift Del (DEL) | VAF 40/94 reads (43%) | catalogued as rs757801068; called by mutect2, pindel, varscan2
- C1orf127 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.984); catalogued as COSV100983408; called by muse, mutect2, varscan2
- C22orf23 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.054); catalogued as COSV99317016; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 82/260 reads (32%) | catalogued as rs762988845; called by mutect2, pindel, varscan2
- C6orf47 | c.512del p.G171Afs*12 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | catalogued as rs1226104140; called by mutect2, pindel, varscan2
- C7orf33 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV100188701; called by muse, mutect2
- C8B | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV100980693; called by muse, mutect2, varscan2
- CAAP1 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100445051; called by muse, mutect2, varscan2
- CABIN1 | c.6065C>T p.A2022V | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as COSV99572730; called by muse, mutect2, varscan2
- CACNA1A | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs773593740, COSV100801034, COSV64212946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53154562; called by muse, mutect2, varscan2
- CACNA1B | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 36/600 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.187); catalogued as COSV53152544; called by muse, mutect2
- CACNA1C | c.1235G>T p.R412M | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100215582; called by muse, mutect2, varscan2
- CACNA1C | c.4040G>A p.R1347Q | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs777058699, COSV100215590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1F | c.2394G>T p.E798D | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100544371; called by muse, varscan2
- CACNG5 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147124881; called by muse, mutect2, varscan2
- CADM1 | c.1026_1028del p.T353del | In Frame Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs767227411; called by pindel, varscan2
- CAMK2G | c.1501G>A p.V501M (on ENST00000423381 / NM_001367518.1; = p.V438M on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.656); catalogued as rs1243870956, COSV55214280; called by muse, mutect2, varscan2
- CAMK2N2 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99955475; called by muse, mutect2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs754747174; called by mutect2, pindel, varscan2
- CAMSAP3 | c.2571G>T p.E857D | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99349897; called by muse, mutect2, varscan2
- CAMTA1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1468781126, COSV100346451; called by muse, mutect2, varscan2
- CANT1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs375819727; called by mutect2, varscan2
- CAP2 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100012119; called by muse, mutect2, varscan2
- CAPN2 | c.1995T>G p.C665W | Missense Mutation (SNP) | VAF 58/936 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99688598; called by muse, mutect2
- CARD10 | c.1493T>C p.M498T | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs770715620, COSV99324638; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARMIL1 | c.1267T>G p.S423A | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100276938; called by muse, mutect2, varscan2
- CARMIL3 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100549265; called by muse, mutect2, varscan2
- CARS1 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99542060; called by muse, mutect2, varscan2
- CARTPT | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99703903; called by muse, mutect2, varscan2
- CASP8AP2 | c.5303A>C p.Q1768P | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV99386774; called by muse, mutect2, varscan2
- CASZ1 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as COSV59736212; called by muse, mutect2, varscan2
- CATSPER4 | c.986A>G p.E329G | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58793819; called by muse, mutect2, varscan2
- CATSPER4 | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100128214; called by muse, varscan2
- CBFB | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753789494, COSV99325478; called by muse, mutect2, varscan2
- CBX8 | c.1155del p.F385Lfs*26 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as COSV99486021; called by mutect2, pindel, varscan2
- CCDC116 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs766787010, COSV53040624, COSV53041926; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC181 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100890260; called by muse, varscan2
- CCDC22 | c.424T>C p.W142R | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100879743; called by muse, mutect2, varscan2
- CCDC22 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100879744; called by muse, mutect2, varscan2
- CCDC39 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 128/297 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.046); catalogued as COSV99867294; called by muse, mutect2, varscan2
- CCDC6 | c.1267T>A p.F423I | Missense Mutation (SNP) | VAF 292/797 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99569163; called by muse, mutect2, varscan2
- CCDC71 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.23); catalogued as COSV100422284; called by muse, mutect2
- CCDC78 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs142180051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC85A | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV68155638; called by mutect2, varscan2
- CCDC9 | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs867167978, COSV55721746, COSV99699549; called by muse, mutect2, varscan2
- CCDC92 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs777304210, COSV99435221; called by muse, mutect2, varscan2
- CCNA1 | c.44T>C p.I15T | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs933815719, COSV99714332; called by muse, mutect2, varscan2
- CCNO | c.829A>C p.S277R | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99248077; called by muse, mutect2
- CCNT2 | c.1217T>A p.V406D | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV99750176; called by muse, mutect2, varscan2
- CD109 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs201515057, COSV99752681; called by muse, mutect2, varscan2
- CD160 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV99353316; called by muse, mutect2
- CD163 | c.3176T>C p.V1059A | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100775683; called by muse, mutect2
- CD163 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV100775687; called by muse, mutect2, varscan2
- CD19 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.373); catalogued as rs148576690; called by muse, mutect2, varscan2
- CD2AP | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100830322; called by muse, varscan2
- CD320 | c.713T>G p.L238R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100035756, COSV56849004; called by muse, mutect2, varscan2
- CD47 | c.459A>G p.I153M | Missense Mutation (SNP) | VAF 155/382 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100790094; called by muse, mutect2, varscan2
- CD93 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV55663248; called by muse, mutect2, varscan2
- CDC20 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 162/450 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs759288917, COSV60522180, COSV60523686; called by muse, varscan2
- CDC5L | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1216747021, COSV65175876; called by muse, mutect2
- CDH4 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV100848436; called by muse, mutect2, varscan2
- CDH7 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59881758; called by muse, mutect2
- CDHR1 | c.1852A>G p.N618D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as COSV100258452; called by muse, mutect2, varscan2
- CDHR2 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.083); catalogued as rs1266638286, COSV99991042; called by muse, mutect2, varscan2
- CDK11B | c.1270A>G p.K424E | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV100477302; called by muse, mutect2, varscan2
- CDK7 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866887561, COSV56516210; called by muse, mutect2, varscan2
- CDYL | c.737G>A p.G246D (on ENST00000328908 / NM_001368125.1; = p.G192D on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV100188749; called by muse, mutect2, varscan2
- CEACAM18 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV101140145; called by muse, mutect2
- CEBPZ | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 36/385 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99135423; called by muse, mutect2
- CELSR1 | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs773813117, COSV53100290; called by muse, mutect2, varscan2
- CELSR2 | c.1553T>C p.V518A | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.405); catalogued as COSV99603107; called by muse, mutect2, varscan2
- CELSR3 | c.8677G>T p.D2893Y | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99372610; called by muse, mutect2, varscan2
- CELSR3 | c.6460C>T p.R2154W | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs143056364; called by muse, mutect2, varscan2
- CEMIP2 | c.3151C>T p.P1051S | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100987071; called by muse, mutect2
- CENPB | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100713310; called by muse, mutect2, varscan2
- CENPE | c.1084-1G>T p.X362_splice | Splice Site (SNP) | VAF 24/152 reads (16%) | catalogued as COSV99477036; called by muse, mutect2, varscan2
- CEP104 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100986336; called by muse, mutect2, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as COSV58068098; called by mutect2, pindel, varscan2
- CEP63 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100132560; called by muse, mutect2, varscan2
- CERK | c.667del p.R223Gfs*94 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as COSV53452916; called by mutect2, pindel, varscan2
- CERS6 | c.560C>G p.S187W | Missense Mutation (SNP) | VAF 114/507 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59836181; called by muse, varscan2
- CETN1 | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100511216; called by muse, mutect2, varscan2
- CFAP100 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1030086287, COSV100729077; called by muse, mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs747835123, COSV61504174; called by mutect2, varscan2
- CFAP69 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV60186102; called by muse, mutect2, varscan2
- CFH | c.3260A>G p.E1087G | Missense Mutation (SNP) | VAF 42/871 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.046); catalogued as COSV100808891; called by muse, mutect2
- CFH | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 51/921 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100808893; called by muse, mutect2
- CFHR2 | c.689A>C p.Y230S | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745329423, COSV100804243; called by muse, mutect2, varscan2
- CGN | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs761721175, COSV54967727; called by muse, mutect2, varscan2
- CHAF1B | c.1607A>G p.Q536R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100023352; called by muse, mutect2, varscan2
- CHAT | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs371719364; called by muse, mutect2, varscan2
- CHAT | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769204680, COSV60333235; called by muse, mutect2, varscan2
- CHCHD2 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs200784526, COSV68170030; called by muse, mutect2, varscan2
- CHCHD6 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99335672; called by muse, mutect2, varscan2
- CHD1 | c.3335G>A p.R1112H | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99399108; called by muse, mutect2
- CHD5 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs567329094, COSV52408139; called by muse, mutect2, varscan2
- CHD7 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101418010; called by mutect2, varscan2
- CHD8 | c.6499G>A p.V2167I (on ENST00000646647 / NM_001170629.2; = p.V1888I on NM_020920.4) | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770593901, COSV63036490, COSV63037040; called by muse, mutect2, varscan2
- CHD8 | c.5881C>T p.R1961C (on ENST00000646647 / NM_001170629.2; = p.R1682C on NM_020920.4) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100765239; called by muse, mutect2, varscan2
- CHML | c.974A>G p.Y325C | Missense Mutation (SNP) | VAF 104/684 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100087045; called by muse, mutect2, varscan2
- CHML | c.296C>G p.T99R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs911830187, COSV59362859; called by muse, mutect2, varscan2
- CHRD | c.1723G>T p.G575C | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754194740, COSV99200242; called by muse, mutect2, varscan2
- CHST5 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748093814, COSV60340362; called by muse, mutect2, varscan2
- CHTF18 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV99135600; called by muse, mutect2, varscan2
- CILK1 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100607524; called by muse, mutect2
- CILP | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs142891097; called by muse, mutect2
- CLCN4 | c.809C>A p.A270E | Missense Mutation (SNP) | VAF 162/417 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101073664; called by muse, mutect2, varscan2
- CLDN11 | c.521T>A p.V174D | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV99290919; called by muse, mutect2
- CLEC18B | c.1114+2T>C p.X372_splice | Splice Site (SNP) | VAF 19/157 reads (12%) | catalogued as COSV100375713; called by mutect2, varscan2
- CLEC3B | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99944511; called by muse, mutect2, varscan2
- CLK1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 116/358 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV100362137; called by muse, mutect2, varscan2
- CLP1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100239726; called by muse, mutect2
- CNGB1 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 14/303 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99201499; called by muse, mutect2
- CNGB3 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs1266563395, COSV100181241; called by muse, mutect2, varscan2
- CNKSR2 | c.1538C>A p.P513H | Missense Mutation (SNP) | VAF 240/683 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV99667425; called by muse, mutect2, varscan2
- CNKSR3 | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527224, COSV72161782, COSV72161814; called by muse, mutect2, varscan2
- CNTN3 | c.2397A>C p.E799D | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV99723343; called by muse, mutect2, varscan2
- CNTN4 | c.2762G>T p.W921L | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100638862; called by muse, mutect2, varscan2
- CNTN6 | c.2961G>T p.E987D | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs1560054638, COSV100610097; called by muse, mutect2, varscan2
- CNTNAP3 | c.2944dup p.V982Gfs*4 | Frame Shift Ins (INS) | VAF 60/214 reads (28%) | catalogued as rs763585044; called by mutect2, pindel, varscan2
- CNTNAP5 | c.2476G>A p.G826R | Missense Mutation (SNP) | VAF 111/302 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867648836, COSV101443075; called by muse, mutect2, varscan2
- COG2 | c.2060A>G p.D687G | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229398920, COSV100794613; called by muse, mutect2
- COG8 | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV99650612; called by muse, mutect2, varscan2
- COL11A1 | c.2428G>T p.D810Y | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62184317; called by muse, mutect2, varscan2
- COL15A1 | c.2793G>A p.Q931= | Splice Region (SNP) | VAF 46/130 reads (35%) | catalogued as rs773693491, COSV100897431; called by muse, mutect2, varscan2
- COL22A1 | c.4420A>G p.K1474E | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs267601787, COSV100276476; called by muse, mutect2, varscan2
- COL27A1 | c.3034-1G>T p.X1012_splice | Splice Site (SNP) | VAF 45/127 reads (35%) | catalogued as COSV100620739; called by muse, mutect2, varscan2
- COL3A1 | c.2384G>A p.G795D | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100482518; called by muse, mutect2, varscan2
- COL3A1 | c.2921A>G p.Q974R | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV100482519; called by muse, mutect2, varscan2
- COL3A1 | c.3770A>C p.N1257T | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.716); catalogued as COSV100482520; called by muse, mutect2
- COL4A1 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101010967, COSV65422992; called by muse, mutect2, varscan2
- COL4A5 | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV100086568; called by muse, mutect2, varscan2
- COL5A1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs375600865, COSV65664570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.7125+2T>C p.X2375_splice | Splice Site (SNP) | VAF 15/116 reads (13%) | catalogued as COSV99796279; called by muse, mutect2, varscan2
- COPS4 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.564); catalogued as COSV100018362, COSV52314359; called by muse, mutect2, varscan2
- CORIN | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99902937; called by muse, mutect2
- CORO7 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs766048891, COSV99227222; called by muse, mutect2, varscan2
- CPN2 | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV100102891, COSV60470930; called by muse, mutect2, varscan2
- CPS1 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV99242245; called by muse, mutect2, varscan2
- CPXCR1 | c.59A>C p.E20A | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV99341977; called by muse, mutect2
- CR1 | c.4942A>T p.R1648W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100887400; called by muse, mutect2, varscan2
- CRACD | c.1460A>T p.D487V | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99948613; called by muse, mutect2, varscan2
- CRAMP1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs754112928; called by mutect2, varscan2
- CRAT | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs552235102, COSV100539819; called by muse, mutect2, varscan2
- CREBBP | c.4063G>A p.G1355R | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774076896, COSV99268651; called by muse, mutect2, varscan2
- CREM | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV100414992; called by muse, mutect2, varscan2
- CRNKL1 | c.2028G>T p.E676D | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV101056842; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 14/18 reads (78%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBG3 | c.6606A>T p.E2202D | Missense Mutation (SNP) | VAF 130/346 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV99476621; called by muse, mutect2, varscan2
- CSDE1 | c.877A>G p.I293V (on ENST00000358528 / NM_001007553.3; = p.I262V on NM_007158.6) | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV54747807, COSV99794094; called by muse, mutect2, varscan2
- CSF2RB | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV99453295; called by muse, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | catalogued as rs747437399; called by mutect2, varscan2
- CSNK1G2 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs548764709, COSV99729595; called by muse, mutect2, varscan2
- CSPG4 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100413447; called by muse, mutect2, varscan2
- CTAGE1 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 144/347 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV101194450; called by muse, mutect2, varscan2
- CTDNEP1 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs759009701, COSV56642186; called by muse, mutect2, varscan2
- CTNND1 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.676); catalogued as COSV100649817; called by muse, mutect2
- CTSB | c.313T>C p.C105R | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100565820; called by muse, mutect2, varscan2
- CTSH | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1410371588, COSV99585353; called by muse, mutect2, varscan2
- CUL7 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs369167170; called by muse, mutect2, varscan2
- CWC15 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs782295901, COSV99688430, COSV99688606; called by muse, mutect2, varscan2
- CWC22 | c.631T>G p.F211V | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99843995; called by muse, mutect2, varscan2
- CX3CR1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV100843128; called by muse, mutect2
- CYP26A1 | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.534); catalogued as COSV99814582; called by muse, mutect2, varscan2
- CYP2C9 | c.693C>A p.N231K | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV99582217; called by muse, mutect2, varscan2
- CYP2F1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs370865507, COSV58527814; called by muse, mutect2, varscan2
- CYP2W1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 141/384 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV58269409; called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1573dup p.W525Lfs*? | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | catalogued as rs778264050; called by mutect2, varscan2
- CYTH2 | c.433A>G p.R145G | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100287047; called by muse, varscan2
- CYTH3 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV100641273; called by muse, mutect2, varscan2
- DAB1 | c.1064T>G p.V355G (on ENST00000371231; = p.V322G on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV100976149; called by muse, mutect2
- DBNL | c.931+1G>A p.X311_splice (on ENST00000448521 / NM_001014436.3; = p.X312_splice on NM_014063.7) | Splice Site (SNP) | VAF 11/27 reads (41%) | catalogued as rs777393608, COSV99803495; called by muse, mutect2, varscan2
- DCAF5 | c.2354T>C p.L785P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.603); catalogued as COSV100432226; called by muse, mutect2, varscan2
- DCAKD | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201376374, COSV60831501; called by muse, mutect2, varscan2
- DCC | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100503138, COSV59082291; called by muse, varscan2
- DCD | c.236del p.G79Dfs*5 | Frame Shift Del (DEL) | VAF 246/620 reads (40%) | catalogued as rs758489970; called by mutect2, varscan2
- DCHS1 | c.5854G>A p.D1952N | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs377529145; called by muse, mutect2, varscan2
- DCLK1 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1212119744, COSV99709232; called by muse, varscan2
- DCLK1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55186866; called by muse, varscan2
- DCLK2 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV99651435; called by muse, mutect2, varscan2
- DCLK2 | c.2239del p.H747Tfs*153 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs751255369; called by pindel, varscan2
- DCLRE1C | c.538G>A p.E180K (on ENST00000378278 / NM_001350965.2; = p.E65K on NM_022487.4) | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV100739735; called by muse, mutect2, varscan2
- DDHD2 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV101240511, COSV68158316; called by muse, mutect2, varscan2
- DDX53 | c.214A>G p.K72E | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100028685; called by muse, mutect2
- DDX6 | c.97G>T p.G33* | Nonsense Mutation (SNP) | VAF 23/447 reads (5%) | catalogued as COSV99870006; called by muse, mutect2
- DDX60L | c.5107A>C p.N1703H | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); catalogued as COSV99486982; called by muse, mutect2
- DENND1A | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101010409; called by muse, mutect2, varscan2
- DENND2A | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs368814564; called by muse, mutect2, varscan2
- DENND2C | c.2478dup p.V827Cfs*15 (on ENST00000393274 / NM_001256404.2; = p.V770Cfs*15 on NM_198459.4) | Frame Shift Ins (INS) | VAF 34/119 reads (29%) | catalogued as rs777741996; called by mutect2, pindel, varscan2
- DENND3 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753582837, COSV52802328; called by muse, mutect2, varscan2
- DENND5B | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs1311405321, COSV60902862; called by muse, mutect2, varscan2
- DGAT1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1315358048, COSV100183925; called by muse, mutect2, varscan2
- DGCR8 | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV100707815; called by muse, mutect2
- DGKZ | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs769790583, COSV100551082; called by muse, varscan2
- DGKZ | c.3212C>T p.A1071V (on ENST00000454345 / NM_001105540.2; = p.A883V on NM_003646.4) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100551084, COSV100551934; called by muse, mutect2, varscan2
- DHX30 | c.2339G>C p.R780P (on ENST00000445061 / NM_138615.3; = p.R741P on NM_014966.3) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99274736; called by muse, mutect2, varscan2
- DHX9 | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841247; called by muse, mutect2
- DICER1 | c.3770T>C p.V1257A | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV100601775; called by muse, mutect2
- DICER1 | c.2933T>G p.L978R | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100601778; called by muse, mutect2, varscan2
- DIDO1 | c.5234del p.G1745Afs*119 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as COSV99825386; called by mutect2, pindel
- DIO1 | c.406T>C p.F136L | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1450868237, COSV100498836; called by muse, mutect2
- DIP2C | c.4634A>G p.D1545G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV99790146; called by muse, mutect2, varscan2
- DISC1 | c.1277G>A p.G426E | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.121); catalogued as COSV99697202, COSV99698708; called by muse, mutect2, varscan2
- DKK1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs145640971; called by muse, mutect2, varscan2
- DLEC1 | c.1425dup p.V476Rfs*58 | Frame Shift Ins (INS) | VAF 33/112 reads (29%) | catalogued as rs756971918; called by mutect2, pindel, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs762874947; called by mutect2, varscan2
- DLL1 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100815931; called by muse, mutect2, varscan2
- DLX4 | c.595C>T p.P199S (on ENST00000240306 / NM_138281.3; = p.P127S on NM_001934.3) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV99537451; called by muse, mutect2
- DMD | c.9764G>A p.G3255E | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626041; called by muse, mutect2, varscan2
- DMD | c.5648A>G p.K1883R | Missense Mutation (SNP) | VAF 19/421 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.174); catalogued as COSV100818222; called by muse, mutect2
- DMD | c.4088A>G p.K1363R | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.283); catalogued as COSV63732568, COSV63756777; called by muse, mutect2
- DMGDH | c.1517G>T p.R506M | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV99668497; called by mutect2, varscan2
- DMP1 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99218508; called by muse, mutect2, varscan2
- DNAH1 | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs905018638, COSV101324768; called by muse, varscan2
- DNAH17 | c.5455C>T p.R1819W | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1032045943, COSV101101505; called by muse, mutect2, varscan2
- DNAH3 | c.12158C>A p.P4053H | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765077; called by muse, mutect2, varscan2
- DNAH5 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV99445374; called by muse, mutect2, varscan2
- DNAH8 | c.7821del p.F2607Lfs*22 | Frame Shift Del (DEL) | VAF 34/141 reads (24%) | catalogued as rs759301439, COSV100547129; called by mutect2, pindel, varscan2
- DNAH9 | c.10380G>T p.E3460D | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV99304246; called by muse, mutect2, varscan2
- DNAJB8 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1022350830, COSV100048105; called by muse, mutect2
- DNAJC10 | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | catalogued as COSV51141666, COSV99898903; called by muse, mutect2
- DNAJC17 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs775459475, COSV99591502; called by muse, mutect2, varscan2
- DNHD1 | c.13433G>A p.R4478Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV54437977; called by muse, mutect2, varscan2
- DNM1 | c.2153C>A p.S718* | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | catalogued as COSV100359524; called by muse, mutect2, varscan2
- DNM3 | c.2582G>A p.R861H (on ENST00000355305 / NM_001350206.2; = p.R855H on NM_015569.5) | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs183558699, COSV100797740; called by muse, mutect2, varscan2
- DOC2A | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV100451201; called by muse, mutect2, varscan2
- DOCK2 | c.3830A>C p.K1277T | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99910440; called by muse, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 13/125 reads (10%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK5 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV52400830; called by muse, mutect2, varscan2
- DOP1A | c.2590A>G p.I864V | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV99381005; called by muse, mutect2, varscan2
- DPH1 | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99559432; called by muse, mutect2, varscan2
- DPP4 | c.9A>T p.T3= | Splice Region (SNP) | VAF 12/128 reads (9%) | catalogued as COSV100858703; called by muse, mutect2
- DPYSL4 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.879); catalogued as rs1398044644, COSV100633839, COSV58308329; called by muse, mutect2, varscan2
- DRC7 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs766595161, COSV61055910; called by muse, mutect2, varscan2
- DRD4 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99448442; called by muse, mutect2, varscan2
- DROSHA | c.2240C>T p.T747M | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs202101007; called by muse, mutect2, varscan2
- DROSHA | c.1834dup p.L612Pfs*8 | Frame Shift Ins (INS) | VAF 21/77 reads (27%) | catalogued as rs1330233722; called by mutect2, pindel, varscan2
- DSC1 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770181232, COSV99937217; called by muse, mutect2, varscan2
- DSCAM | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 47/123 reads (38%) | catalogued as COSV101259183; called by muse, mutect2, varscan2
- DSEL | c.1347G>T p.K449N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100025291; called by muse, mutect2, varscan2
- DSG2 | c.1393T>C p.Y465H | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99852765; called by muse, mutect2
- DSP | c.7706C>A p.T2569N | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV101131185; called by muse, mutect2, varscan2
- DST | c.4972G>A p.A1658T | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV99751401; called by muse, mutect2
- DUOX1 | c.4019G>T p.G1340V | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100367641; called by muse, mutect2, varscan2
- DUS3L | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100287893; called by muse, mutect2, varscan2
- DUSP10 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs751183346, COSV100100127; called by muse, mutect2, varscan2
- DVL2 | c.1801del p.A601Qfs*80 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs745455027; called by mutect2, pindel, varscan2
- E2F5 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 32/119 reads (27%) | catalogued as COSV99809297; called by muse, mutect2, varscan2
- ECI1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs773367840, COSV100066508; called by muse, varscan2
- EDIL3 | c.864del p.I289* | Frame Shift Del (DEL) | VAF 80/234 reads (34%) | catalogued as COSV99676088; called by mutect2, pindel, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 24/129 reads (19%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EDNRB | c.500C>T p.T167M (on ENST00000377211 / NM_001201397.1; = p.T77M on NM_000115.5) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1227502849, COSV57527236; called by muse, mutect2, varscan2
- EEA1 | c.4048G>A p.A1350T | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as COSV100467091; called by muse, mutect2, varscan2
- EED | c.1119G>A p.W373* | Nonsense Mutation (SNP) | VAF 23/130 reads (18%) | catalogued as COSV99646121; called by muse, mutect2, varscan2
- EEF1AKNMT | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 103/285 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100675773; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1301C>T p.S434F (on ENST00000361735 / NM_015935.5; = p.S348F on NM_014955.3) | Missense Mutation (SNP) | VAF 62/180 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.299); catalogued as COSV100675774; called by muse, mutect2, varscan2
- EFCAB12 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.833); catalogued as rs372347992, COSV58176335; called by mutect2, varscan2
- EFNA3 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 130/322 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV100860792; called by muse, mutect2, varscan2
- EFR3A | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99602476; called by muse, varscan2
- EGLN2 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763273304, COSV100393643; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 66/157 reads (42%) | catalogued as rs746692720; called by mutect2, varscan2
- EGR3 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100416107, COSV57832880; called by muse, mutect2
- EHMT1 | c.3059G>A p.R1020H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs376628665; ClinVar: likely benign; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs1377283633; called by mutect2, varscan2
- EIF2S3 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 61/778 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99450680; called by muse, mutect2
- EIF4G1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1560210274, COSV100071490; called by muse, mutect2, varscan2
- EIF4G2 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV60596538; called by muse, mutect2, varscan2
- EIF4H | c.247+2T>C p.X83_splice | Splice Site (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99733283; called by muse, mutect2, varscan2
- EIF5B | c.2404-1G>T p.X802_splice | Splice Site (SNP) | VAF 378/990 reads (38%) | catalogued as COSV99176822; called by muse, varscan2
- ELAPOR2 | c.2081G>A p.S694N (on ENST00000450689 / NM_001142749.3; = p.S527N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51883899; called by muse, mutect2
- ELF5 | c.80G>A p.C27Y (on ENST00000312319 / NM_198381.2; = p.C17Y on NM_001422.4) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.648); catalogued as rs1355366001, COSV99141152; called by muse, mutect2, varscan2
- ELL2 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 282/744 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99427216; called by muse, mutect2, varscan2
- EMILIN1 | c.1275G>T p.E425D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.237); catalogued as COSV99565772; called by muse, varscan2
- EMSY | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV100595419; called by muse, mutect2, varscan2
- ENC1 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100187906; called by muse, mutect2, varscan2
- ENKUR | c.359del p.K120Sfs*22 | Frame Shift Del (DEL) | VAF 58/191 reads (30%) | catalogued as COSV58632229; called by mutect2, pindel, varscan2
- ENO2 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs892519952, COSV99145125; called by muse, mutect2, varscan2
- ENOX2 | c.1066C>T p.R356W (on ENST00000338144 / NM_001382520.1; = p.R327W on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1169558988, COSV57656151; called by muse, mutect2, varscan2
- EPB41L1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs993735906, COSV52435435; called by muse, mutect2, varscan2
- EPHA2 | c.719dup p.E241* | Frame Shift Ins (INS) | VAF 13/64 reads (20%) | catalogued as rs1412658647; called by mutect2, pindel, varscan2
- EPHB6 | c.165+1del | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs771807343; called by mutect2, pindel, varscan2
- EPS8L2 | c.1412dup p.D473Gfs*30 | Frame Shift Ins (INS) | VAF 24/122 reads (20%) | catalogued as rs780857388; called by mutect2, varscan2
- ERBB2 | c.3656A>G p.N1219S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.269); catalogued as rs889372358, COSV99506771; called by muse, mutect2, varscan2
- ERBB3 | c.2830A>C p.M944L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99915868; called by muse, mutect2, varscan2
- ERBB4 | c.1169A>T p.N390I | Missense Mutation (SNP) | VAF 197/557 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99616933; called by muse, mutect2, varscan2
- ERCC2 | c.1384T>C p.S462P | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101228696; called by muse, mutect2, varscan2
- ERF | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV99724499; called by muse, mutect2, varscan2
- ERICH3 | c.1440A>C p.K480N | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100443455; called by muse, mutect2
- ERN1 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101458386; called by muse, mutect2
- ERRFI1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs746056102, COSV66311447; called by muse, mutect2, varscan2
- ERVFRD-1 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100977342; called by muse, mutect2, varscan2
- ESR1 | c.154T>C p.Y52H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.87); catalogued as COSV99237955; called by muse, mutect2, varscan2
- ESX1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.347); catalogued as rs1556395640, COSV65423900; called by muse, mutect2, varscan2
- ETV5 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100112058; called by muse, mutect2
- EVC | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs748220728, COSV53829599; called by muse, mutect2, varscan2
- EVPL | c.5183C>A p.T1728N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100043998; called by muse, mutect2, varscan2
- EXOC2 | c.61T>C p.W21R | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV100032866; called by muse, varscan2
- EXOC5 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100566978; called by muse, mutect2
- EYA4 | c.1633A>G p.R545G (on ENST00000531901 / NM_001301013.1; = p.R539G on NM_004100.5) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100765212; called by muse, mutect2, varscan2
- F8 | c.560T>C p.L187S | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM053264, CM122062, CM1314143, COSV100811253; called by muse, mutect2, varscan2
- FAAH | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 154/418 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99679882; called by muse, mutect2, varscan2
- FAM102A | c.484A>G p.I162V (on ENST00000373095 / NM_001035254.3; = p.I20V on NM_203305.2) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs776105165, COSV100305406; called by muse, mutect2, varscan2
- FAM110B | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs750259825, COSV64064745, COSV99058572; called by muse, mutect2, varscan2
- FAM117B | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.855); catalogued as rs1354071673, COSV100287169; called by muse, mutect2, varscan2
- FAM120C | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs1557129591, COSV60262480; called by muse, mutect2, varscan2
- FAM126A | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as COSV101299986; called by muse, mutect2, varscan2
- FAM13B | c.601A>C p.M201L | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.087); catalogued as COSV99220999; called by muse, mutect2, varscan2
- FAM151A | c.344A>C p.H115P | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100156752; called by muse, mutect2, varscan2
- FAM160B2 | c.242A>C p.E81A | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99248741; called by muse, mutect2, varscan2
- FAM166A | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs770828085, COSV100457680; called by muse, mutect2, varscan2
- FAM178B | c.1752G>T p.K584N (on ENST00000490605 / NM_001122646.3; = p.K24N on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.277); catalogued as COSV100013764; called by muse, mutect2, varscan2
- FAM193A | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100218586; called by muse, mutect2, varscan2
- FAM193A | c.1991G>T p.R664M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100218589; called by muse, mutect2, varscan2
- FAM217A | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 56/128 reads (44%) | catalogued as rs371728702; called by muse, mutect2, varscan2
- FAM222B | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV100368224; called by muse, mutect2, varscan2
- FAM47B | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV100264075; called by muse, mutect2
- FAM83F | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100328842; called by muse, mutect2, varscan2
- FAM83H | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782638461, COSV101186922; called by muse, mutect2, varscan2
- FAM86B1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100392082; called by mutect2, varscan2
- FANCA | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs752799441, COSV101224668; called by muse, mutect2, varscan2
- FANCD2 | c.3895C>T p.R1299C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs555348798, COSV55043462; called by muse, mutect2, varscan2
- FANCD2OS | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs757747853, COSV101090990; called by muse, mutect2, varscan2
- FANCI | c.2323T>A p.F775I | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100167494; called by muse, mutect2, varscan2
- FAR2 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456494412, COSV99478754; called by muse, mutect2, varscan2
- FARSB | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99918173; called by muse, mutect2, varscan2
- FASN | c.5761C>T p.R1921W | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142537824, COSV100147342; called by muse, mutect2, varscan2
- FAT1 | c.8799del p.G2934Vfs*3 | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | catalogued as rs113224498; called by mutect2, pindel, varscan2
- FAT1 | c.277T>C p.F93L | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101499075; called by muse, varscan2
- FAT2 | c.9043C>A p.L3015I | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV99941735; called by muse, mutect2, varscan2
- FAT4 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.204); catalogued as COSV101271942, COSV101272530; called by muse, mutect2
- FAT4 | c.2617G>A p.V873M | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV101271943; called by muse, mutect2, varscan2
- FAT4 | c.2722G>A p.A908T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.383); catalogued as COSV101271945; called by muse, mutect2, varscan2
- FAT4 | c.9859A>G p.N3287D | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100627296; called by muse, mutect2, varscan2
- FBF1 | c.6A>G p.A2= | Splice Region (SNP) | VAF 71/196 reads (36%) | catalogued as rs937181889, COSV99503299; called by muse, mutect2, varscan2
- FBH1 | c.2884C>T p.R962C (on ENST00000362091 / NM_178150.3; = p.R1013C on NM_032807.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs151032401; called by mutect2, varscan2
- FBN2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV99325117; called by muse, mutect2, varscan2
- FBXL18 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV101212022; called by muse, mutect2, varscan2
- FBXL6 | c.1519T>C p.S507P | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100095496; called by muse, mutect2, varscan2
- FCER2 | c.191-1G>A p.X64_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100689503; called by muse, mutect2, varscan2
- FCN2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV99391100; called by muse, mutect2, varscan2
- FCRL2 | c.760C>A p.R254S | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs764532671, COSV100829833, COSV63835060; called by muse, mutect2, varscan2
- FCSK | c.2483T>C p.L828P | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99850507; called by muse, mutect2, varscan2
- FER | c.788T>C p.F263S | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV99811692; called by muse, mutect2, varscan2
- FETUB | c.187A>G p.R63G | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99408872; called by muse, mutect2, varscan2
- FETUB | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV54004768, COSV99408873; called by muse, mutect2, varscan2
- FGD1 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100910806; called by muse, mutect2, varscan2
- FGD1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as COSV100910807; called by muse, mutect2, varscan2
- FGF7 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV99983266; called by muse, mutect2, varscan2
- FGFRL1 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99294454; called by muse, mutect2, varscan2
- FHOD3 | c.3812G>C p.R1271T (on ENST00000359247 / NM_001281739.3; = p.R1288T on NM_025135.5) | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV57180702; called by muse, mutect2, varscan2
- FHOD3 | c.3975G>T p.E1325D (on ENST00000359247 / NM_001281739.3; = p.E1342D on NM_025135.5) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99940192; called by mutect2, varscan2
- FILIP1 | c.3116T>A p.V1039D | Missense Mutation (SNP) | VAF 48/676 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs920705479, COSV99383946; called by muse, mutect2
- FLG | c.2996C>T p.A999V | Missense Mutation (SNP) | VAF 193/480 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100910557; called by muse, varscan2
- FLG2 | c.3870A>C p.E1290D | Missense Mutation (SNP) | VAF 84/946 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.112); catalogued as COSV101165605; called by muse, mutect2
- FLII | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100493472; called by muse, mutect2, varscan2
- FLNA | c.6863G>A p.R2288H (on ENST00000369850 / NM_001110556.2; = p.R2280H on NM_001456.3) | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.342); catalogued as rs782275601, COSV100774292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774294; called by muse, mutect2, varscan2
- FLRT1 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.917); catalogued as rs369112014, COSV99734514; called by muse, mutect2, varscan2
- FLRT2 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100420017, COSV58151627; called by muse, mutect2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV56098414; called by mutect2, pindel
- FMN1 | c.3520G>A p.V1174M (on ENST00000616417 / NM_001277313.2; = p.V951M on NM_001103184.4) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs760909779, COSV100568039; called by muse, mutect2, varscan2
- FMNL1 | c.3045G>T p.E1015D | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.688); catalogued as COSV100056190; called by muse, mutect2, varscan2
- FMO4 | c.1558del p.A520Hfs*18 | Frame Shift Del (DEL) | VAF 26/156 reads (17%) | catalogued as rs770011693, COSV100882071; called by mutect2, pindel, varscan2
- FMOD | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs376310218; called by muse, mutect2, varscan2
- FMR1NB | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 174/495 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100789520; called by muse, mutect2, varscan2
- FN3K | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV100333206; called by muse, mutect2, varscan2
- FN3KRP | c.610T>C p.F204L | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV99484914; called by muse, mutect2, varscan2
- FNDC1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99794975; called by muse, mutect2, varscan2
- FNDC1 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as rs770479635, COSV51945671; called by muse, mutect2, varscan2
- FNDC3B | c.3165del p.T1056Pfs*7 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | catalogued as rs769012096; called by pindel, varscan2
- FOLR3 | c.517del p.A173Pfs*61 | Frame Shift Del (DEL) | VAF 67/187 reads (36%) | catalogued as rs1231432460; called by mutect2, pindel, varscan2
- FOXC1 | c.1550G>A p.G517D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101083226; called by muse, mutect2, varscan2
- FOXD4L1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 206/283 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV99380246; called by muse, mutect2, varscan2
- FOXE1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as rs1456874527, COSV100909851; called by muse, mutect2, varscan2
- FOXK1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); catalogued as rs373966273; called by muse, mutect2, varscan2
- FOXP2 | c.1160T>C p.V387A | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100646257; called by muse, mutect2, varscan2
- FREM2 | c.8518T>C p.F2840L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99746946; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 14/31 reads (45%) | catalogued as rs752538869; called by mutect2, varscan2
- FRMPD3 | c.3377C>T p.T1126I | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV99345719; called by muse, mutect2, varscan2
- FRMPD3 | c.4334T>A p.V1445D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV99345723; called by muse, mutect2, varscan2
- FRY | c.5498T>A p.V1833D | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100968814; called by muse, mutect2, varscan2
- FRY | c.5983T>A p.S1995T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV100968815; called by muse, mutect2, varscan2
- FSD2 | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV100575016; called by muse, mutect2, varscan2
- FTO | c.1220G>T p.W407L | Missense Mutation (SNP) | VAF 202/570 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101149561; called by muse, mutect2, varscan2
- FTSJ3 | c.1017A>T p.E339D | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.814); catalogued as COSV100037178; called by muse, mutect2, varscan2
- FXR2 | c.1768C>A p.R590S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100001979; called by mutect2, varscan2
- FZR1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs754635012, COSV100553401; called by muse, mutect2, varscan2
- G3BP1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs187250945, COSV62366143; called by muse, mutect2, varscan2
- GABBR2 | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99409259; called by muse, mutect2, varscan2
- GABRG1 | c.815A>T p.Y272F | Missense Mutation (SNP) | VAF 133/371 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV99777438; called by muse, mutect2, varscan2
- GAK | c.3242A>G p.D1081G | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100033178; called by muse, mutect2, varscan2
- GALNS | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141340188, CM145576, COSV99242890; called by muse, mutect2, varscan2
- GALNT10 | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV99768259; called by muse, mutect2, varscan2
- GALNT10 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99768264; called by muse, mutect2, varscan2
- GALNT5 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV99374857; called by muse, mutect2, varscan2
- GALNT9 | c.1445C>T p.A482V (on ENST00000328957 / NM_001122636.2; = p.A116V on NM_021808.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs569920280, COSV61097833, COSV61098339; called by mutect2, varscan2
- GALNTL6 | c.1369dup p.E457Gfs*33 | Frame Shift Ins (INS) | VAF 18/103 reads (17%) | catalogued as rs1177099840; called by mutect2, pindel, varscan2
- GATA1 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 56/363 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs141479621, COSV99060288; called by muse, mutect2, varscan2
- GCNA | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as COSV101032399, COSV101032542; called by muse, mutect2, varscan2
- GCNT2 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as COSV101097218; called by muse, mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 19/52 reads (37%) | catalogued as rs768450027; called by mutect2, varscan2
- GDI1 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV100870653; called by muse, mutect2, varscan2
- GDI1 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99340857; called by muse, mutect2, varscan2
- GFI1 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.225); catalogued as COSV99647417; called by muse, mutect2, varscan2
- GFRA1 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100815469; called by muse, mutect2, varscan2
- GFRA1 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV100815472; called by muse, mutect2, varscan2
- GGT7 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV100321750; called by muse, mutect2, varscan2
- GGT7 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs780547379, COSV60540261, COSV60540732, COSV60541939; called by muse, mutect2, varscan2
- GGT7 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1358907971, COSV99489591; called by muse, mutect2
- GHR | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.384); catalogued as COSV100049921; called by muse, mutect2
- GIMAP4 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.575); catalogued as COSV99750442; called by muse, mutect2, varscan2
- GINS1 | c.240G>A p.L80= | Splice Region (SNP) | VAF 59/158 reads (37%) | catalogued as COSV99319960; called by muse, mutect2, varscan2
- GLB1L | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773279693, COSV99850253; called by muse, mutect2, varscan2
- GLB1L2 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs760777420, COSV60279885; called by muse, mutect2, varscan2
- GLCCI1 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 34/387 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as COSV99780118; called by muse, mutect2
- GLE1 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100012339; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 44/156 reads (28%) | catalogued as rs759448855, COSV99954330; called by pindel, varscan2
- GMEB2 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as rs148884295; called by muse, mutect2, varscan2
- GMIP | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99179086; called by muse, mutect2, varscan2
- GNA14 | c.34_36del p.K12del | In Frame Del (DEL) | VAF 17/44 reads (39%) | catalogued as rs754882574; called by mutect2, pindel, varscan2
- GNG13 | c.96C>T p.P32= | Splice Region (SNP) | VAF 16/61 reads (26%) | catalogued as rs373613761, COSV99243318; called by muse, mutect2, varscan2
- GOLGA3 | c.4133C>T p.A1378V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs760377464, COSV99202272; called by mutect2, varscan2
- GOPC | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99270702; called by muse, mutect2, varscan2
- GP1BA | c.1480del p.T494Pfs*59 | Frame Shift Del (DEL) | VAF 78/239 reads (33%) | catalogued as rs759573909; called by mutect2, pindel, varscan2
- GP5 | c.230A>C p.Q77P | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV99756317; called by muse, varscan2
- GPATCH8 | c.169C>T p.Q57* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as COSV100132477; called by muse, mutect2, varscan2
- GPBP1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs761214960, COSV99302430; called by muse, mutect2, varscan2
- GPD1L | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1330401782, COSV99245539; called by muse, mutect2, varscan2
- GPM6A | c.71del p.G24Afs*7 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as COSV54541068; called by mutect2, pindel, varscan2
- GPR101 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 31/120 reads (26%) | catalogued as COSV53239711; called by muse, mutect2, varscan2
- GPR135 | c.1090G>C p.A364P | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV101229289; called by muse, mutect2, varscan2
- GPR151 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.095); catalogued as rs1378863861, COSV99694423; called by muse, mutect2, varscan2
- GPR152 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs760895810, COSV100351434; called by muse, mutect2, varscan2
- GPR153 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100928457; called by muse, mutect2, varscan2
- GPR34 | c.1010T>C p.I337T | Missense Mutation (SNP) | VAF 171/452 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100586827; called by muse, mutect2, varscan2
- GPR42 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 65/536 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.615); catalogued as COSV101497372; called by muse, mutect2, varscan2
- GPX4 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1373540032, COSV100684120; called by muse, mutect2, varscan2
- GRAP2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs755090425, COSV100702889; called by muse, mutect2, varscan2
- GRHL2 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 29/410 reads (7%) | catalogued as COSV99306092; called by muse, mutect2
- GRIA3 | c.2576T>A p.L859H | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV99989052; called by muse, mutect2
- GRIK4 | c.246C>T p.T82= | Splice Region (SNP) | VAF 15/46 reads (33%) | catalogued as COSV101483453; called by muse, mutect2, varscan2
- GRIN2C | c.2533C>A p.H845N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99500596; called by muse, mutect2, varscan2
- GRIP1 | c.1838+2T>C p.X613_splice (on ENST00000359742 / NM_001379345.1; = p.X561_splice on NM_021150.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99668111; called by muse, mutect2, varscan2
- GRIPAP1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1557062822, COSV100904202; called by muse, mutect2, varscan2
- GRM2 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as COSV99622472; called by muse, mutect2
- GRM5 | c.2794C>T p.R932C (on ENST00000305447 / NM_001143831.2; = p.R900C on NM_000842.4) | Missense Mutation (SNP) | VAF 51/580 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1565316730, COSV100550314; called by muse, mutect2
- GRM7 | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100735774; called by muse, mutect2, varscan2
- GRN | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1386649838, COSV99274593; called by mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | catalogued as rs754199513; called by mutect2, varscan2
- GSTM2 | c.113-1G>T p.X38_splice | Splice Site (SNP) | VAF 96/468 reads (21%) | catalogued as COSV99598050; called by muse, mutect2, varscan2
- GUCA1B | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99273817; called by muse, mutect2, varscan2
- GUCY1A1 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 108/270 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99637176; called by muse, varscan2
- GXYLT1 | c.1225del p.T409Qfs*17 | Frame Shift Del (DEL) | VAF 41/149 reads (28%) | catalogued as rs1222708103; called by mutect2, pindel, varscan2
- GYG2 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201973951, COSV58550595; called by muse, mutect2
- GYS1 | c.2158A>G p.S720G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV99620436; called by mutect2, varscan2
- GYS2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99679447; called by muse, mutect2, varscan2
- H1-3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99768567, COSV99768682; called by muse, mutect2
- H6PD | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs371234309, COSV101072420; called by muse, mutect2, varscan2
- HAVCR2 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV100324638; called by muse, mutect2, varscan2
- HCFC1 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100128460; called by muse, mutect2
- HDAC3 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100539423; called by muse, mutect2, varscan2
- HDAC5 | c.2793dup p.I932Hfs*24 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | catalogued as rs770174487; called by mutect2, varscan2
- HDLBP | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100189946; called by muse, mutect2, varscan2
- HECTD1 | c.6121del p.I2041Lfs*27 | Frame Shift Del (DEL) | VAF 90/292 reads (31%) | catalogued as rs758518381; called by mutect2, pindel, varscan2
- HECTD1 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781483780, COSV67945115; called by muse, mutect2, varscan2
- HECTD4 | c.10550C>G p.P3517R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as COSV101106745; called by muse, mutect2, varscan2
- HELB | c.3221T>C p.I1074T | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99921608; called by muse, mutect2
- HELZ2 | c.4630G>A p.E1544K (on ENST00000467148 / NM_001037335.2; = p.E975K on NM_033405.3) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs759047851, COSV101427522; called by muse, mutect2, varscan2
- HELZ2 | c.3208G>A p.A1070T (on ENST00000467148 / NM_001037335.2; = p.A501T on NM_033405.3) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100915440; called by muse, mutect2, varscan2
- HENMT1 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 111/293 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898638; called by muse, mutect2, varscan2
- HERC1 | c.13163C>T p.A4388V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs755893599, COSV71247724; called by mutect2, varscan2
- HERC2 | c.7444C>A p.L2482I | Missense Mutation (SNP) | VAF 133/382 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as COSV99871186; called by muse, mutect2, varscan2
- HES6 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99800658; called by muse, mutect2, varscan2
- HEXB | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs533645939, COSV54669777; called by muse, mutect2, varscan2
- HEY2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1345318496, COSV64240338, COSV64240832; called by muse, mutect2, varscan2
- HFM1 | c.2754T>A p.C918* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99645412; called by muse, varscan2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HIC2 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV101335533, COSV101335615, COSV68042195; called by muse, mutect2, varscan2
- HIGD1B | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs370827709; called by muse, mutect2, varscan2
- HINFP | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100640819; called by muse, mutect2, varscan2
- HIP1R | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs756668419, COSV99458303; called by muse, mutect2, varscan2
- HIPK2 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100702056; called by muse, mutect2, varscan2
- HIVEP3 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56014611; called by muse, mutect2, varscan2
- HK3 | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs746886792, COSV52842174, COSV99457875; called by muse, mutect2, varscan2
- HKDC1 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.173); catalogued as COSV100664372; called by muse, mutect2, varscan2
- HMCN1 | c.13589G>T p.G4530V | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99624428; called by muse, mutect2, varscan2
- HMCN1 | c.16792C>T p.R5598* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as rs193921043, COSV54900490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMGCS2 | c.829del p.I277Sfs*22 | Frame Shift Del (DEL) | VAF 60/190 reads (32%) | catalogued as rs1557991740, COSV65568693; called by pindel, varscan2
- HNF1A | c.1136del p.P379Lfs*5 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as COSV57466638; called by mutect2, pindel, varscan2
- HNRNPUL2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.322); catalogued as rs761674867, COSV100079405; called by muse, mutect2, varscan2
- HOXB13 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284791; called by muse, mutect2, varscan2
- HOXC12 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs975446722, COSV99678647; called by muse, mutect2, varscan2
- HPRT1 | c.583T>A p.Y195N | Missense Mutation (SNP) | VAF 210/583 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100053061; called by muse, mutect2, varscan2
- HRAS | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs142218590, COSV99530370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HROB | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV99809110; called by muse, mutect2, varscan2
- HSPA2 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99904701; called by muse, mutect2, varscan2
- HSPA6 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); catalogued as rs773522375, COSV100553916; called by muse, mutect2, varscan2
- HSPB8 | c.266dup p.P90Tfs*37 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs773017653; called by mutect2, varscan2
- HSPG2 | c.889T>C p.C297R | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101012893; called by muse, mutect2, varscan2
- HTN1 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as COSV99887437; called by muse, varscan2
- HTRA2 | c.346del p.A116Qfs*93 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs779457274; called by pindel, varscan2
- HTT | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.77); catalogued as rs556061424, COSV100750440; called by muse, mutect2, varscan2
- HTT | c.4235G>A p.R1412H | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201053245, COSV100750441; called by muse, mutect2, varscan2
- HTT | c.8015C>T p.S2672L | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.175); catalogued as rs202216456, COSV61858110; called by muse, mutect2, varscan2
- HUWE1 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99470715; called by muse, mutect2, varscan2
- IDH1 | c.544A>T p.M182L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.228); catalogued as COSV100576054, COSV100577057; called by muse, mutect2, varscan2
- IDH3G | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs782820935, COSV99472955; called by muse, mutect2, varscan2
- IFIT1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs376965843; called by muse, mutect2, varscan2
- IFRD2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369995042; called by muse, mutect2, varscan2
- IFRD2 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100269275; called by muse, mutect2, varscan2
- IFT122 | c.3393C>T p.S1131= (on ENST00000348417 / NM_052989.3; = p.S1072= on NM_018262.4) | Splice Region (SNP) | VAF 40/103 reads (39%) | catalogued as rs767085658, COSV99958760; called by muse, mutect2, varscan2
- IGDCC4 | c.3283C>T p.P1095S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.477); catalogued as COSV100732709; called by muse, mutect2, varscan2
- IGF2R | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs746024088, COSV63628877; called by muse, mutect2, varscan2
- IGHV4-34 | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs767163665; called by muse, mutect2
- IGLC2 | c.281G>T p.S94I | Missense Mutation (SNP) | VAF 66/668 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as rs759610154; called by muse, mutect2
- IGSF21 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs766575681, COSV52139296; called by muse, mutect2, varscan2
- IGSF9B | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs1463019856, COSV100317026; called by muse, mutect2, varscan2
- IHO1 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV99605832; called by muse, mutect2, varscan2
- IKZF1 | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as COSV58791367; called by muse, varscan2
- IL12B | c.970T>C p.S324P | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99180323; called by muse, mutect2
- IL1RAPL2 | c.1589T>G p.L530R | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV100780745; called by muse, mutect2, varscan2
- IL7R | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57415505; called by muse, mutect2
- ILDR1 | c.911del p.P304Lfs*32 (on ENST00000344209 / NM_001199799.2; = p.P260Lfs*32 on NM_175924.4) | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | catalogued as rs1189980243, COSV56553280; called by mutect2, pindel, varscan2
- ILDR2 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99613250; called by muse, mutect2, varscan2
- IMPA1 | c.303-2dup p.X101_splice | Splice Site (INS) | VAF 24/104 reads (23%) | catalogued as rs763126450; called by mutect2, varscan2
- INO80D | c.590del p.P197Lfs*23 | Frame Shift Del (DEL) | VAF 70/193 reads (36%) | catalogued as COSV68959090, COSV68960091; called by mutect2, pindel, varscan2
- INPP5D | c.1357G>A p.E453K (on ENST00000445964 / NM_001017915.3; = p.E452K on NM_005541.5) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV64035382; called by muse, mutect2, varscan2
- INSC | c.737T>A p.I246N | Missense Mutation (SNP) | VAF 109/275 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV101088786; called by muse, mutect2, varscan2
- INTS3 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100015650; called by muse, mutect2, varscan2
- INTS8 | c.2611G>A p.V871M | Missense Mutation (SNP) | VAF 171/476 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs922690273, COSV100569141; called by muse, mutect2, varscan2
- IQGAP1 | c.3790C>T p.R1264W | Missense Mutation (SNP) | VAF 93/213 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs763205486, COSV51591287; called by muse, mutect2, varscan2
- IQSEC2 | c.2903C>A p.P968H (on ENST00000642864 / NM_001111125.3; = p.P763H on NM_015075.2) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100944745; called by muse, mutect2, varscan2
- IRAG1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as rs375197703, COSV70212209; called by muse, mutect2, varscan2
- IRF1 | c.667+2T>C p.X223_splice | Splice Site (SNP) | VAF 9/62 reads (15%) | catalogued as COSV55377394; called by muse, mutect2, varscan2
- IRS1 | c.483A>C p.K161N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100524030; called by muse, mutect2, varscan2
- IRX2 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs773758165, COSV100121578; called by muse, mutect2, varscan2
- ISG20 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100043893; called by muse, mutect2, varscan2
- ISLR | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs199636609, COSV99997444; called by mutect2, varscan2
- ITGA10 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs1048394371, COSV100994727; called by muse, mutect2, varscan2
- ITGA7 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV99144343; called by muse, mutect2, varscan2
1,899 further variants in this file (1,285 protein-altering or splice-affecting, 566 silent, 48 other) are not listed here.
